Gene-level copy-number profile of tumor specimen TCGA-DK-A3X1-01A from TCGA case TCGA-DK-A3X1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 78.7 years (28,757 days).
Specimen TCGA-DK-A3X1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.4dfd5a1e-a268-4d9a-898c-4575abb813f0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3X1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2795eb34-1549-43fa-b283-7f33e46b25c4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 242; copy number 2: 9,561; copy number 3: 25,446; copy number 4: 18,020; copy number 5: 3,190; copy number 6: 838; copy number 7: 1,251; copy number 8: 247; copy number 9: 139; copy number 10: 419; copy number 11: 233; copy number 12: 67; copy number 15: 31; copy number 19: 130.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3X1-01A-12D-A22Y-01): tumor purity 0.47, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,517 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,031,203–153,460,651, 25 genes, copy number 11: SPRR1B, SPRR2D, SPRR2A, SPRR2B, SPRR2E, SPRR2F, SPRR2C, SPRR2G, AL161636.1, LELP1, PRR9, AL161636.2, LORICRIN, PGLYRP3, PGLYRP4, RNU6-160P, S100A9, S100A12, LAPTM4BP1, S100A8, S100A15A, S100A7A, S100A7P1, S100A7L2, S100A7.
- chr1:157,674,321–173,489,407, 433 genes, copy number 10–11 (within-gene range 2–11) (broad region; genes not listed).
- chr1:173,824,653–174,160,165, 12 genes, copy number 10 (within-gene range 2–10): DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT.
- chr3:10,992,186–11,846,919, 14 genes, copy number 8 (within-gene range 4–8): SLC6A1, SLC6A1-AS1, AC066580.1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3, TAMM41.
- chr3:14,178,817–17,205,165, 67 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:64,500,825–67,770,468, 112 genes, copy number 9–12 (broad region; genes not listed).
- chr8:79,918,860–80,080,775, 1 gene, copy number 12 (within-gene range 6–12): AC036214.3.
- chr8:80,032,724–85,828,467, 104 genes, copy number 7–12 (broad region; genes not listed).
- chr8:85,851,446–85,861,562, 1 gene, copy number 7 (within-gene range 4–7): LINC02849.
- chr8:95,204,456–95,811,254, 1 gene, copy number 8 (within-gene range 4–8): C8orf37-AS1.
- chr8:95,505,406–106,272,902, 208 genes, copy number 8–19 (broad region; genes not listed).
- chr14:74,285,269–80,959,517, 140 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr14:91,232,532–106,875,071, 680 genes, copy number 7 (broad region; genes not listed).
- chr17:52,390,515–68,763,882, 424 genes, copy number 7–11 (broad region; genes not listed).
- chr18:47,390–11,885,685, 246 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr20:22,684,958–22,746,991, 2 genes, copy number 8 (within-gene range 3–8): AL158175.1, KRT18P3.
- chr20:31,257,664–32,167,258, 47 genes, copy number 7 (within-gene range 3–7): DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1.

Autosomal genes at a single copy (total copy number 1): 242. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
